Gene-level copy-number profile of tumor specimen TCGA-D7-6521-01A from TCGA case TCGA-D7-6521, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; Tumor grade: G3; Age at diagnosis: 65.1 years (23,776 days).
Specimen TCGA-D7-6521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.45579fb9-3767-4032-9774-080739cffd12.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6521-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72f36ad7-1955-4c54-b19a-ca5a2a36f305

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,670; copy number 2: 37,328; copy number 3: 11,098; copy number 4: 3,332; copy number 5: 135; copy number 6: 22; copy number 7: 78; copy number 8: 6; copy number 9: 4; copy number 10: 15; copy number 11: 122.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6521-01A-11D-1799-01): tumor purity 0.23, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:77,650,274–77,927,028, 1 gene (within-gene range 0–1): MEI4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,343,316–163,769,691, 117 genes, copy number 5 (broad region; genes not listed).
- chr1:166,895,711–167,591,846, 18 genes, copy number 5: ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1.
- chr7:91,638,847–92,447,813, 15 genes, copy number 10 (within-gene range 4–10): AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P.
- chr7:95,772,506–100,520,205, 145 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:105,532,169–106,908,980, 22 genes, copy number 6 (within-gene range 3–6): RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG.
- chr7:110,590,082–111,562,517, 6 genes, copy number 8: AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.
- chr7:115,935,148–118,513,830, 55 genes, copy number 7: TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1.
- chr7:119,495,024–120,227,213, 4 genes, copy number 9 (within-gene range 3–9): LINC02476, RNU1-29P, AC004946.1, AC004946.2.

Autosomal genes at a single copy (total copy number 1): 7,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
